Gene-level copy-number profile of tumor specimen C3N-02261-01 from CPTAC case C3N-02261, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oncocytoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 57.1 years (20,860 days).
Specimen C3N-02261-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 84675f59-55db-48a8-92cd-a1423ca11356.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02261-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/471493fb-f4cb-4c16-8333-9daab8428144

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 5,599; copy number 2: 20,406; copy number 3: 16,277; copy number 4: 5,663; copy number 5: 5,674; copy number 6: 4,774; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr16:32,379,071–32,441,159, 3 genes: ACTR3BP3, AC138915.2, PABPC1P13.
- chr16:32,635,673–32,636,045, 1 gene: AC133569.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,449 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–10,684,768, 297 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–181,342,213, 2,901 genes, copy number 5–6 (broad region; genes not listed).
- chr11:86,649–20,575,042, 697 genes, copy number 5 (within-gene range 5–10) (broad region; genes not listed).
- chr11:48,216,810–135,075,908, 2,217 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–106,879,812, 2,250 genes, copy number 5–6 (broad region; genes not listed).
- chr16:32,600,299–32,615,639, 1 gene, copy number 8: AC137800.1.
- chr16:33,577,502–33,622,547, 1 gene, copy number 5 (within-gene range 4–5): AC142384.1.
- chr20:87,250–51,905,030, 1,112 genes, copy number 5 (broad region; genes not listed).
- chr20:56,358,974–64,327,972, 245 genes, copy number 5 (broad region; genes not listed).
- chr21:13,305,152–46,691,226, 718 genes, copy number 5 (broad region; genes not listed).
- chr22:18,527,802–18,719,341, 10 genes, copy number 6: TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 5,599. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
